CGCI case BLGSP-71-30-00676 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/96305351-9dd4-4f0e-9639-4c247399ac20

Demographics
Sex at birth: male; Age at index: 28 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Colon, NOS; Classification of tumor: primary; Age at diagnosis: 28.2 years (10,292 days); Year of diagnosis: 2009; Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage II; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 3,481 days (9.5 years); Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, adult; Max tumor bulk site: Colon; Sites of involvement: Colon, NOS.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Mesenteric; Tumor largest dimension diameter: 6.8 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CODOX-M; Days to treatment start: -2 days; Days to treatment end: 118 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-IVAC; Days to treatment start: -2 days; Days to treatment end: 118 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Cytarabine + Doxorubicin + Etoposide + Ifosfamide + Methotrexate + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: -2 days; Days to treatment end: 118 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; ECOG performance status: 2.
- Days to follow up: 3,481 days (9.5 years); Disease response: Tumor Free.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- CD5 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Abnormal, NOS.
- MYC translocation (FISH): Positive.
- Epstein-Barr Virus: Negative.
- Lactate Dehydrogenase 97 [Blood test normal range upper: 180].

Other clinical attributes
- Day 0: Comorbidities: Hypothyroidism.
- Day 0: Weight: 72 kg; Height: 190 cm; BMI: 19.9.

Biospecimens (2 samples)
- Sample BLGSP-71-30-00676-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Colon; Preservation method: FFPE; Days to sample procurement: 0 days; Tissue collection type: Retrospective.
- Sample BLGSP-71-30-00676-01Z: Sample type: Tumor; Tissue type: Tumor.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: Yes; New tumor event diagnosis indicator: No.
- History of disease: History immunological disease other: Hypothyroidism.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 1; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: endoscopic biopsy; Lymph nodes examined: No.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 97; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD5.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: CODOXMR/IVACR (Magrath protocol); Pharma adjuvant cycles count: 4.

Additional fields from the CGCI biospecimen supplement workbook CGCI-BLGSP_biospecimenSupplementSpreadsheet_TWIST_20220304.xlsx (sheet Sheet1), for sample BLGSP-71-30-00676-01A-01E-0001-01:
- % tumour: 90
